Somatic mutation profile of tumor specimen TCGA-86-8280-01A (aliquot TCGA-86-8280-01A-11D-2284-08) from TCGA case TCGA-86-8280, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 54.7 years (19,977 days).
Specimen TCGA-86-8280-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bdffdc6-ab76-468b-ab2e-dc69f3e8620c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-8280-10A (Blood Derived Normal), aliquot TCGA-86-8280-10A-01D-2284-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3307d2d2-5e85-4dfa-8458-959837cab5e1

The open-access MAF lists 49 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 38, Silent 9, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 13/58 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 25/115 reads (22%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.578A>C p.H193P | Missense Mutation (SNP) | VAF 24/59 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS1 | c.2707C>T p.P903S | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV99536133; called by muse, mutect2, varscan2
- ANKRD26 | c.3136G>T p.D1046Y | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101063228; called by muse, mutect2, varscan2
- ASIC3 | c.869A>G p.N290S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as rs774073299, COSV99876959; called by muse, mutect2, varscan2
- ATRNL1 | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV100745539; called by muse, mutect2
- BBOX1 | c.952G>C p.V318L | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99589654; called by muse, mutect2
- BPTF | c.1019A>C p.Y340S | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100074965; called by muse, mutect2, varscan2
- CABP4 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1347952534, COSV56888159; called by muse, mutect2, varscan2
- CNN1 | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as rs746981990, COSV99370585; called by muse, mutect2, varscan2
- CNNM4 | c.928A>T p.M310L | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV100998668; called by muse, mutect2, varscan2
- COL18A1 | c.2014G>A p.D672N (on ENST00000359759 / NM_130444.3; = p.D437N on NM_030582.4) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.305); catalogued as COSV100700685; called by muse, mutect2
- CPLANE1 | c.8201A>G p.H2734R | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs541921016, COSV99950573; called by muse, mutect2, varscan2
- DCAF7 | c.791A>G p.N264S | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.139); catalogued as COSV100177664; called by muse, mutect2, varscan2
- DDX4 | c.1986T>C p.D662= | Splice Region (SNP) | VAF 17/200 reads (9%) | catalogued as COSV100737526; called by muse, mutect2
- FAM90A1 | c.1041G>T p.Q347H | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as COSV56709820; called by muse, varscan2
- FAM90A1 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.982); catalogued as COSV56713245; called by muse, varscan2
- FAM90A1 | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.127); catalogued as COSV100274313; called by muse, varscan2
- FAT3 | c.13414G>A p.D4472N | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.52); catalogued as COSV53126279; called by muse, mutect2, varscan2
- FCRL5 | c.1932C>G p.H644Q | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV100708941; called by muse, mutect2, varscan2
- GAS6 | c.2002C>T p.H668Y | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1400467008, COSV100581537; called by muse, mutect2
- GRIN2A | c.3029C>G p.P1010R | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV100409785; called by muse, mutect2, varscan2
- GZF1 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.943); catalogued as COSV57637673; called by muse, mutect2, varscan2
- HIC2 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1226322603, COSV68042538; called by muse, mutect2, varscan2
- HSPA12B | c.904G>T p.G302C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.927); catalogued as COSV53923293; called by muse, mutect2, varscan2
- KCNA5 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99363896; called by muse, mutect2
- LAMB4 | c.4558G>A p.D1520N | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs201217649, COSV99224074; called by muse, mutect2
- LRRC61 | c.391G>C p.D131H | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99784647; called by muse, mutect2, varscan2
- MECR | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.019); catalogued as COSV99747058; called by muse, mutect2
- MYO7B | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV67344334, COSV67346872; called by muse, mutect2, varscan2
- OR1J1 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV99403157; called by muse, mutect2, varscan2
- PCDHA11 | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.014); catalogued as COSV100250425; called by muse, mutect2
- PCDHB4 | c.2227A>T p.T743S | Missense Mutation (SNP) | VAF 40/337 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV99522201; called by muse, mutect2, varscan2
- PTPN13 | c.6919A>G p.M2307V (on ENST00000411767 / NM_080683.3; = p.M2288V on NM_006264.3) | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761708222, COSV100364766; called by muse, mutect2
- STK11 | c.352T>C p.Y118H | Missense Mutation (SNP) | VAF 10/217 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100480381; called by muse, mutect2
- TMOD3 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100419095; called by muse, mutect2, varscan2
- TRPV1 | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99439607; called by muse, mutect2, varscan2
- UHRF1BP1L | c.4344C>G p.H1448Q | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.99); PolyPhen benign (0.012); catalogued as COSV99691613; called by muse, mutect2, varscan2
- UHRF1BP1L | c.4343A>T p.H1448L | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99691614; called by muse, mutect2, varscan2
- ARID2 | c.1503C>T p.S501= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV100536198; called by muse, mutect2, varscan2
- MRC1 | c.1314T>C p.S438= | Silent (SNP) | VAF 22/420 reads (5%) | called by muse, mutect2
- MUC16 | c.30855C>A p.A10285= | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as COSV101199949; called by muse, mutect2, varscan2
- NHS | c.3624C>T p.C1208= | Silent (SNP) | VAF 36/201 reads (18%) | catalogued as rs111534978, CM071900, COSV101196431; called by muse, mutect2, varscan2
- OCA2 | c.42G>A p.A14= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs762670171, COSV100667885, COSV62343461; called by muse, mutect2
- PDZD4 | c.1389G>A p.S463= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as rs1557075938, COSV99381337; called by muse, mutect2, varscan2
- PSMB5 | c.105C>T p.L35= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as rs749585868, COSV100557356; called by muse, mutect2, varscan2
- STIL | c.2931C>T p.Y977= | Silent (SNP) | VAF 12/219 reads (5%) | catalogued as COSV99680960; called by muse, mutect2
- TRIOBP | c.5607C>T p.A1869= (on ENST00000644935 / NM_001039141.3; = p.A156= on NM_007032.5) | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as rs1180026057, COSV100462296; called by muse, mutect2, varscan2
